Gene-level copy-number profile of tumor specimen TCGA-77-8143-01A from TCGA case TCGA-77-8143, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 76.0 years (27,772 days).
Specimen TCGA-77-8143-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.6dab672d-6818-44a7-b39d-caa90b7c027d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-8143-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/684e709e-17f3-4eab-8960-6c74fa6d4f8d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 3; copy number 2: 19,801; copy number 3: 23,829; copy number 4: 11,677; copy number 5: 334; copy number 6: 3,408; copy number 7: 226; copy number 8: 48; copy number 9: 185; copy number 10: 158; copy number 11: 20; copy number 12: 17; copy number 13: 6; copy number 14: 74; copy number 17: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-8143-01A-11D-2243-01): tumor purity 0.66, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:287,440–352,723, 1 gene (within-gene range 0–2): AXIN1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 760 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:26,847,747–32,821,051, 139 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr2:39,082,589–39,437,301, 7 genes, copy number 11 (within-gene range 3–11): RNU6-198P, HSPE1P13, Y_RNA, CDKL4, MAP4K3, AC007684.1, AC007684.2.
- chr2:39,736,060–53,860,160, 197 genes, copy number 8–17 (within-gene range 3–17) (broad region; genes not listed).
- chr2:64,330,481–65,271,253, 33 genes, copy number 7: AC114752.1, AC114752.2, MIR4433B, MIR4433A, RPL23AP37, LGALSL-DT, AC008074.1, LGALSL, LINC01805, AC008074.2, AFTPH, MIR4434, RNU6-100P, LINC02579, SERTAD2, AC007365.1, RPS10P9, RN7SL341P, Y_RNA, AC007880.1, LINC01800, LINC02245, RN7SL211P, RPL11P1, SLC1A4, RNU6-548P, LINC02576, CEP68, RAB1A, SNORA74, AC007318.1, VDAC2P5, ACTR2.
- chr6:54,624,605–54,945,099, 6 genes, copy number 13: RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1.
- chr7:47,275,154–48,647,497, 12 genes, copy number 10 (within-gene range 4–10): TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13.
- chr7:49,773,638–56,650,696, 133 genes, copy number 8–10 (within-gene range 6–10) (broad region; genes not listed).
- chr8:38,901,235–46,028,892, 113 genes, copy number 7–11 (broad region; genes not listed).
- chr11:11,841,423–15,930,951, 66 genes, copy number 7–14 (broad region; genes not listed).
- chr11:15,969,533–15,969,621, 1 gene, copy number 7: MIR6073.
- chr11:68,707,440–70,436,584, 53 genes, copy number 10 (within-gene range 6–10): TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
